Somatic mutation profile of tumor specimen ALCH-B3IN-TTP1-A (aliquot ALCH-B3IN-TTP1-A-1-0-D-A80D-36) from ALCHEMIST case ALCH-B3IN, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 70.5 years (25,765 days).
Specimen ALCH-B3IN-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 00573380-80d2-4703-b635-2ef6d120c625.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3IN-NB1-A (Blood Derived Normal), aliquot ALCH-B3IN-NB1-A-1-0-D-A80D-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/28d8ffc2-311a-445e-8d48-60c022b897fc

The open-access MAF lists 287 somatic variants for this specimen: 202 protein-altering or splice-affecting, 50 silent, 35 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 175, Silent 50, Nonsense Mutation 19, Intron 13, 3'UTR 6, 5'UTR 5, Splice Site 5, RNA 5, 3'Flank 4, Splice Region 2, 5'Flank 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 37/257 reads (14%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCG1 | c.893G>A p.R298Q | Missense Mutation (SNP) | VAF 18/245 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.042); catalogued as rs776796182, COSV100493924, COSV59203805; called by muse, mutect2
- ADAMTS12 | c.377T>A p.L126H | Missense Mutation (SNP) | VAF 11/228 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.096); catalogued as COSV61273018; called by muse, mutect2
- ADGRF3 | c.2135C>T p.S712F (on ENST00000311519 / NM_001145168.1; = p.S513F on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/319 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.611); catalogued as rs530265216; called by muse, mutect2
- AQP3 | c.455C>G p.S152C | Missense Mutation (SNP) | VAF 34/516 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV53049162; called by muse, mutect2
- BNC1 | c.1708C>T p.Q570* | Nonsense Mutation (SNP) | VAF 24/340 reads (7%) | catalogued as COSV61758439; called by muse, mutect2
- CBLN2 | c.221C>A p.A74E | Missense Mutation (SNP) | VAF 16/272 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.233); catalogued as COSV54050115; called by muse, mutect2
- CCP110 | c.1423C>T p.H475Y | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.134); catalogued as COSV66818215; called by muse, mutect2
- CLCN2 | c.1139C>T p.P380L | Missense Mutation (SNP) | VAF 34/376 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs778766766; called by muse, mutect2
- CSMD3 | c.9806C>A p.A3269D (on ENST00000297405 / NM_001363185.1; = p.A3100D on NM_052900.3) | Missense Mutation (SNP) | VAF 38/275 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52289038; called by muse, varscan2
- CSNK1A1L | c.26C>A p.A9D | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs1361082267; called by muse, mutect2
- CT47B1 | c.656C>A p.A219E | Missense Mutation (SNP) | VAF 53/625 reads (8%) | SIFT tolerated (0.58); PolyPhen benign (0.031); catalogued as rs750373515, COSV64890986; called by muse, mutect2
- CWH43 | c.989G>C p.C330S | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.061); catalogued as COSV56938391; called by muse, mutect2
- DACH1 | c.2216C>G p.T739R (on ENST00000619232 / NM_001366712.1; = p.T485R on NM_004392.6) | Missense Mutation (SNP) | VAF 21/306 reads (7%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.156); catalogued as COSV100498556; called by muse, mutect2
- DMXL1 | c.7619G>A p.R2540Q | Missense Mutation (SNP) | VAF 22/355 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.295); catalogued as rs1380673147, COSV100223813, COSV60716707; called by muse, mutect2
- DNAH3 | c.9693C>G p.N3231K | Missense Mutation (SNP) | VAF 9/195 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1228154334; called by muse, mutect2
- ELP4 | c.1030G>A p.D344N (on ENST00000350638; = p.D343N on NM_019040.5) | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as rs1339815498; called by muse, mutect2
- FGFR2 | c.883G>T p.E295* | Nonsense Mutation (SNP) | VAF 19/157 reads (12%) | catalogued as COSV60656486; called by muse, mutect2
- FOXJ3 | c.1106C>G p.S369* | Nonsense Mutation (SNP) | VAF 10/195 reads (5%) | catalogued as COSV100692007; called by muse, mutect2
- GJB4 | c.667C>G p.R223G | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV58356320; called by muse, mutect2, varscan2
- GNAO1 | c.661G>T p.A221S | Missense Mutation (SNP) | VAF 28/358 reads (8%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.942); catalogued as COSV52613526; called by muse, mutect2
- GPM6A | c.388-1G>A p.X130_splice | Splice Site (SNP) | VAF 8/78 reads (10%) | catalogued as COSV99705707; called by muse, mutect2
- GPR137 | c.952C>T p.R318W | Missense Mutation (SNP) | VAF 20/197 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs1281700916; called by muse, mutect2, varscan2
- GPR158 | c.3027G>T p.W1009C | Missense Mutation (SNP) | VAF 18/299 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs373052680, COSV66282253; called by muse, mutect2
- GRM3 | c.580G>A p.D194N | Missense Mutation (SNP) | VAF 18/444 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100862005; called by muse, mutect2
- GRM8 | c.1880C>T p.T627M | Missense Mutation (SNP) | VAF 16/242 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.86); catalogued as rs142400397, COSV58834505; called by muse, mutect2
- H2AC12 | c.32C>G p.A11G | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV63617442; called by muse, mutect2
- JAKMIP1 | c.1295C>T p.P432L | Missense Mutation (SNP) | VAF 17/186 reads (9%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs374764524; called by muse, mutect2, varscan2
- KCNA4 | c.551G>T p.G184V | Missense Mutation (SNP) | VAF 14/218 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100069261; called by muse, mutect2
- KCNJ12 | c.37G>T p.V13L | Missense Mutation (SNP) | VAF 16/398 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.315); catalogued as COSV59169099; called by muse, mutect2
- KCNQ1 | c.553G>C p.V185L | Missense Mutation (SNP) | VAF 43/521 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.325); catalogued as rs749351255, COSV50100550; called by muse, mutect2
- KRT12 | c.500G>T p.G167V | Missense Mutation (SNP) | VAF 16/209 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as rs74952061; called by muse, mutect2
- LRRC24 | c.763C>T p.L255F | Missense Mutation (SNP) | VAF 17/298 reads (6%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.997); catalogued as rs1223372128; called by muse, mutect2
- LRRC37B | c.1237G>A p.E413K | Missense Mutation (SNP) | VAF 28/446 reads (6%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs1213454348; called by muse, mutect2
- LRRC8B | c.1888C>T p.Q630* | Nonsense Mutation (SNP) | VAF 7/82 reads (9%) | catalogued as COSV58377507, COSV58377547; called by muse, mutect2
- MAML2 | c.2782G>A p.G928R | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.4); catalogued as rs781431200, COSV73262875; called by muse, mutect2
- MAPKAP1 | c.1012G>C p.D338H | Missense Mutation (SNP) | VAF 20/356 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as COSV99784413; called by muse, mutect2
- MARCHF9 | c.878C>G p.S293C | Missense Mutation (SNP) | VAF 12/232 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.213); catalogued as rs1329621867, COSV56984654; called by muse, mutect2
- MINDY2 | c.143C>A p.T48N | Missense Mutation (SNP) | VAF 16/212 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs533078522; called by muse, mutect2
- MKI67 | c.8818G>C p.D2940H | Missense Mutation (SNP) | VAF 20/376 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.265); catalogued as COSV64075350; called by muse, mutect2
- MPO | c.1231G>T p.E411* | Nonsense Mutation (SNP) | VAF 57/438 reads (13%) | catalogued as COSV56565413; called by muse, mutect2, varscan2
- MS4A15 | c.199C>G p.L67V | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV100558850; called by muse, mutect2
- MYH9 | c.1383G>A p.L461= | Splice Region (SNP) | VAF 20/506 reads (4%) | catalogued as COSV53392446; called by muse, mutect2
- NCAN | c.1171G>T p.E391* | Nonsense Mutation (SNP) | VAF 18/234 reads (8%) | catalogued as rs780022532, COSV53059351; called by muse, mutect2
- NCF2 | c.823G>C p.D275H | Missense Mutation (SNP) | VAF 20/399 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62314735, COSV62316287; called by muse, mutect2
- NEK8 | c.1378A>G p.T460A | Missense Mutation (SNP) | VAF 28/275 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs1197910839; called by muse, mutect2
- NFE2L3 | c.710C>A p.P237H | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.436); catalogued as rs1365509208; called by muse, mutect2
- OR4C16 | c.382C>A p.L128M | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV58944701; called by mutect2, varscan2
- PCDH9 | c.3283G>T p.D1095Y (on ENST00000377865 / NM_203487.3; = p.D1061Y on NM_020403.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/161 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV60534955; called by muse, mutect2
- PCDHA6 | c.1870G>T p.V624L | Missense Mutation (SNP) | VAF 18/328 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.611); catalogued as COSV65343443; called by muse, mutect2
- PDGFRB | c.2222T>C p.M741T | Missense Mutation (SNP) | VAF 15/243 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs1171332049; called by muse, mutect2
- POT1 | c.410G>T p.R137L | Missense Mutation (SNP) | VAF 107/335 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587777475, CM144558, COSV62931229, COSV62935193; called by muse, mutect2, varscan2
- POTEC | c.185G>T p.G62V | Missense Mutation (SNP) | VAF 43/324 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.476); catalogued as rs545692763; called by muse, mutect2, varscan2
- PSG2 | c.471C>A p.N157K | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.074); catalogued as rs1426188497; called by muse, mutect2
- PSG8 | c.1217C>A p.S406Y | Missense Mutation (SNP) | VAF 21/203 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs891936994, COSV60611646; called by muse, mutect2
- PTPRO | c.1046G>T p.W349L | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99839849; called by muse, mutect2, varscan2
- RGS18 | c.227C>G p.S76C | Missense Mutation (SNP) | VAF 6/109 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.413); catalogued as COSV100817682; called by muse, mutect2
- RGS21 | c.443G>T p.W148L | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.164); catalogued as COSV69881766; called by muse, mutect2
- RHOH | c.133G>A p.V45I | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.984); catalogued as rs760810812; called by muse, mutect2, varscan2
- RIOK2 | c.1002C>G p.F334L | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV99300114; called by muse, mutect2
- RYR2 | c.5346C>A p.F1782L | Missense Mutation (SNP) | VAF 20/352 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.1); catalogued as COSV63700281; called by muse, mutect2
- SHC3 | c.1003G>T p.D335Y | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.163); catalogued as rs1381472613; called by muse, mutect2
- SLC10A2 | c.782A>T p.E261V | Missense Mutation (SNP) | VAF 16/269 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1269620135; called by muse, mutect2
- SPPL2C | c.1037G>C p.R346P | Missense Mutation (SNP) | VAF 33/224 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.677); catalogued as rs779097529, COSV61293954; called by muse, mutect2, varscan2
- SRCAP | c.1069C>T p.H357Y | Missense Mutation (SNP) | VAF 7/147 reads (5%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.015); catalogued as COSV52670507; called by muse, mutect2
- SYNPO | c.1433C>T p.S478L (on ENST00000394243 / NM_001166208.2; = p.S234L on NM_007286.6) | Missense Mutation (SNP) | VAF 15/402 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.447); catalogued as rs1172898956; called by muse, mutect2
- SYT4 | c.420G>T p.K140N | Missense Mutation (SNP) | VAF 6/109 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.105); catalogued as rs1234656164, COSV54899138; called by muse, mutect2
- TNR | c.362C>A p.P121H | Missense Mutation (SNP) | VAF 37/344 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375494839, COSV54868118; called by muse, mutect2, varscan2
- TSHZ3 | c.614G>C p.G205A | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV53664111; called by muse, mutect2
- TSPEAR | c.664G>T p.G222C | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1329340778, COSV59981997; called by muse, mutect2, varscan2
- VENTX | c.608G>A p.W203* | Nonsense Mutation (SNP) | VAF 25/164 reads (15%) | catalogued as COSV58084091; called by muse, mutect2, varscan2
- ZNF835 | c.1270G>A p.G424S | Missense Mutation (SNP) | VAF 12/169 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV73379531; called by muse, mutect2
- ABCA6 | c.1979G>T p.R660L | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- ABCF2-H2BE1 | c.1138-1G>C p.X380_splice | Splice Site (SNP) | VAF 10/133 reads (8%) | called by muse, mutect2
- AC244197.3 | c.370C>A p.H124N | Missense Mutation (SNP) | VAF 22/405 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- ACBD5 | c.230A>C p.Q77P (on ENST00000375888 / NM_001352568.1; = p.Q79P on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/201 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ACVR2B | c.1256G>T p.G419V | Missense Mutation (SNP) | VAF 36/445 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ADCY1 | c.3205G>C p.G1069R | Missense Mutation (SNP) | VAF 44/556 reads (8%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); called by muse, mutect2
- ADGRB3 | c.1675T>A p.W559R | Missense Mutation (SNP) | VAF 20/157 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AGAP2 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 13/234 reads (6%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.727); called by muse, mutect2
- ALDOB | c.907G>A p.G303R | Missense Mutation (SNP) | VAF 22/300 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ANKEF1 | c.1270G>A p.G424R | Missense Mutation (SNP) | VAF 13/225 reads (6%) | SIFT tolerated (0.57); PolyPhen benign (0.08); called by muse, mutect2
- ANTXRL | c.1617C>A p.H539Q | Missense Mutation (SNP) | VAF 26/247 reads (11%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.946); called by muse, mutect2
- AP002512.3 | c.563T>C p.L188S | Missense Mutation (SNP) | VAF 25/211 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ARHGAP6 | c.1231C>A p.P411T | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATG12 | c.28C>T p.Q10* | Nonsense Mutation (SNP) | VAF 8/80 reads (10%) | called by muse, mutect2
- BCL11B | c.2235del p.E746Rfs*66 (on ENST00000357195 / NM_001282237.2; = p.E675Rfs*66 on NM_022898.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 45/442 reads (10%) | called by mutect2, pindel, varscan2
- BEND3 | c.1804G>T p.G602C | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- BFSP1 | c.65C>A p.S22* | Nonsense Mutation (SNP) | VAF 9/187 reads (5%) | called by muse, mutect2
- BICC1 | c.1048G>T p.G350C | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BSN | c.6031G>C p.D2011H | Missense Mutation (SNP) | VAF 8/196 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2
- C1QTNF5 | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.548); called by muse, mutect2
- C4A | c.2770G>T p.G924* | Nonsense Mutation (SNP) | VAF 102/1183 reads (9%) | called by muse, mutect2
- CALM2 | c.394G>A p.D132N | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.104); called by muse, mutect2
- CCDC71 | c.1170G>T p.R390S | Missense Mutation (SNP) | VAF 18/237 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.25); called by muse, mutect2
- CCDC83 | c.706A>G p.K236E | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- CD14 | c.87T>A p.D29E | Missense Mutation (SNP) | VAF 29/199 reads (15%) | SIFT tolerated (0.94); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CEP112 | c.2818A>G p.R940G (on ENST00000392769 / NM_001353127.1; = p.R196G on NM_001037325.3) | Missense Mutation (SNP) | VAF 15/164 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- CHRNA5 | c.1144A>G p.S382G | Missense Mutation (SNP) | VAF 22/218 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CLCA4 | c.2065C>A p.L689I | Missense Mutation (SNP) | VAF 12/202 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.222); called by muse, mutect2
- CLN3 | c.502G>T p.G168W (on ENST00000360019 / NM_001286104.2; = p.G192W on NM_000086.2) | Missense Mutation (SNP) | VAF 24/274 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- COL18A1 | c.1259G>T p.W420L | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- COL19A1 | c.1675G>A p.E559K | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- COL26A1 | c.260G>A p.G87E | Missense Mutation (SNP) | VAF 26/280 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); called by muse, mutect2
- CRNN | c.1405G>T p.G469C | Missense Mutation (SNP) | VAF 14/218 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2
- CSMD3 | c.986C>A p.T329K | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); called by muse, mutect2
- CYP4A11 | c.442C>A p.P148T | Missense Mutation (SNP) | VAF 12/226 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2
- DCAF12L2 | c.1310A>G p.N437S | Missense Mutation (SNP) | VAF 22/275 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- DICER1 | c.1265A>C p.E422A | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.643); called by muse, mutect2
- DLL1 | c.55-2A>T p.X19_splice | Splice Site (SNP) | VAF 22/103 reads (21%) | called by muse, mutect2, varscan2
- DYRK3 | c.424A>G p.T142A | Missense Mutation (SNP) | VAF 17/185 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.024); called by muse, mutect2
- EDC4 | c.2506G>C p.E836Q | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); called by muse, mutect2
- EIF3A | c.2170C>G p.L724V | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- ERICH3 | c.3784G>T p.G1262* | Nonsense Mutation (SNP) | VAF 23/361 reads (6%) | called by muse, mutect2
- EXD3 | c.340C>G p.L114V | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, varscan2
- F5 | c.4710G>C p.W1570C | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- FERMT1 | c.922A>C p.T308P | Missense Mutation (SNP) | VAF 22/340 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FOXL1 | c.488A>T p.Q163L | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FTMT | c.145C>A p.L49M | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- FZR1 | c.636G>T p.W212C | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2
- GCKR | c.433G>T p.V145L | Missense Mutation (SNP) | VAF 11/297 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2
- GFRA1 | c.513G>T p.R171S | Missense Mutation (SNP) | VAF 15/205 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GH2 | c.558C>A p.Y186* | Nonsense Mutation (SNP) | VAF 54/736 reads (7%) | called by muse, mutect2
- GIP | c.125T>C p.V42A | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.001); called by muse, mutect2
- GJD2 | c.548C>A p.T183N | Missense Mutation (SNP) | VAF 7/148 reads (5%) | SIFT tolerated (0.49); PolyPhen benign (0.023); called by muse, mutect2
- GLO1 | c.468T>C p.G156= | Splice Region (SNP) | VAF 8/42 reads (19%) | called by muse, mutect2, varscan2
- GPR137 | c.1177C>T p.P393S | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRIA2 | c.233G>T p.C78F | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- H2AC20 | c.276G>C p.E92D | Missense Mutation (SNP) | VAF 27/485 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.041); called by muse, mutect2
- HIBADH | c.797G>T p.G266V | Missense Mutation (SNP) | VAF 5/120 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.106); called by muse, mutect2
- HS3ST2 | c.5C>A p.A2D | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.108); called by muse, mutect2
- HSPB6 | c.31T>A p.W11R | Missense Mutation (SNP) | VAF 26/340 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); called by muse, mutect2
- HTR7 | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 14/234 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- IDH3B | c.317A>G p.E106G | Missense Mutation (SNP) | VAF 50/642 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.124); called by muse, mutect2
- IRS4 | c.1032C>A p.S344R | Missense Mutation (SNP) | VAF 38/510 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); called by muse, mutect2
- IRX5 | c.1351G>T p.D451Y | Missense Mutation (SNP) | VAF 24/368 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); called by muse, mutect2
- KCNH1 | c.1115T>A p.I372N (on ENST00000271751 / NM_172362.3; = p.I345N on NM_002238.4) | Missense Mutation (SNP) | VAF 22/268 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- KIAA1109 | c.13842A>T p.Q4614H | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2
- KLKB1 | c.1627G>T p.V543L | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.017); called by muse, mutect2
- L3MBTL3 | c.865-2A>T p.X289_splice | Splice Site (SNP) | VAF 17/85 reads (20%) | called by muse, mutect2, varscan2
- LAMB1 | c.3376G>T p.D1126Y | Missense Mutation (SNP) | VAF 31/142 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.418); called by muse, mutect2, varscan2
- LAMC3 | c.4562C>A p.S1521Y | Missense Mutation (SNP) | VAF 38/335 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- LTC4S | c.356T>A p.V119E | Missense Mutation (SNP) | VAF 37/313 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- MAGEB6B | c.958A>T p.I320F | Missense Mutation (SNP) | VAF 24/346 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.423); called by muse, mutect2
- MAST4 | c.6832G>T p.D2278Y (on ENST00000403625 / NM_001164664.2; = p.D2089Y on NM_015183.3) | Missense Mutation (SNP) | VAF 7/142 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.382); called by muse, mutect2
- MEIOC | c.2773G>C p.D925H | Missense Mutation (SNP) | VAF 16/189 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.421); called by muse, mutect2
- METTL2A | c.1111A>T p.K371* | Nonsense Mutation (SNP) | VAF 26/139 reads (19%) | called by muse, mutect2, varscan2
- MIB2 | c.1184G>T p.G395V | Missense Mutation (SNP) | VAF 8/175 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- MIDN | c.490C>T p.Q164* | Nonsense Mutation (SNP) | VAF 9/86 reads (10%) | called by muse, mutect2
- MIXL1 | c.275C>G p.S92C | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- MTCP1 | c.254G>T p.W85L | Missense Mutation (SNP) | VAF 9/198 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2
- MYH9 | c.978G>A p.M326I | Missense Mutation (SNP) | VAF 21/496 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.025); called by muse, mutect2
- MYO7B | c.470G>T p.S157I | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NDST1 | c.1567-1G>T p.X523_splice | Splice Site (SNP) | VAF 23/331 reads (7%) | called by muse, mutect2
- NKX6-1 | c.1058G>C p.G353A | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- NLRC3 | c.2990C>A p.A997D | Missense Mutation (SNP) | VAF 12/231 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); called by muse, mutect2
- NR0B1 | c.644G>C p.C215S | Missense Mutation (SNP) | VAF 24/325 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- NR6A1 | c.1011C>G p.S337R (on ENST00000487099 / NM_033334.4; = p.S332R on NM_001489.5) | Missense Mutation (SNP) | VAF 17/271 reads (6%) | SIFT tolerated (0.55); PolyPhen benign (0.029); called by muse, mutect2
- NTRK2 | c.860C>A p.P287Q | Missense Mutation (SNP) | VAF 12/226 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OPN1MW | c.899A>T p.H300L | Missense Mutation (SNP) | VAF 27/434 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR2AG1 | c.271A>C p.T91P | Missense Mutation (SNP) | VAF 14/189 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.775); called by muse, mutect2
- OR6B1 | c.595G>T p.D199Y | Missense Mutation (SNP) | VAF 20/288 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2
- OR6C1 | c.416G>A p.C139Y | Missense Mutation (SNP) | VAF 18/212 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- P2RX1 | c.823G>C p.E275Q | Missense Mutation (SNP) | VAF 14/400 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.011); called by muse, mutect2
- PCDH15 | c.1804T>G p.Y602D | Missense Mutation (SNP) | VAF 24/360 reads (7%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.979); called by muse, mutect2
- PIP5K1C | c.316G>C p.D106H | Missense Mutation (SNP) | VAF 14/446 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PKD2L1 | c.2229G>C p.W743C | Missense Mutation (SNP) | VAF 12/218 reads (6%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.174); called by muse, mutect2
- PLEKHA6 | c.2827G>A p.E943K | Missense Mutation (SNP) | VAF 23/437 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2
- PLXNA3 | c.1044C>A p.H348Q | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.576); called by muse, mutect2
- PLXNA3 | c.2925C>A p.C975* | Nonsense Mutation (SNP) | VAF 5/74 reads (7%) | called by muse, mutect2
- R3HDM2 | c.1020G>C p.M340I | Missense Mutation (SNP) | VAF 44/355 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- RNF44 | c.269G>A p.S90N | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.72); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RP1L1 | c.4665G>T p.Q1555H | Missense Mutation (SNP) | VAF 20/262 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.104); called by muse, mutect2
- RPS4X | c.118G>T p.E40* | Nonsense Mutation (SNP) | VAF 18/212 reads (8%) | called by muse, mutect2
- RTL1 | c.3780G>T p.Q1260H | Missense Mutation (SNP) | VAF 55/485 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SHROOM2 | c.1819A>T p.T607S | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.001); called by muse, mutect2
- SIX6 | c.534C>A p.N178K | Missense Mutation (SNP) | VAF 36/514 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); called by muse, mutect2
- SLC25A18 | c.590C>A p.S197Y | Missense Mutation (SNP) | VAF 13/276 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SLC25A28 | c.238G>T p.A80S | Missense Mutation (SNP) | VAF 15/258 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.897); called by muse, mutect2
- SLC38A5 | c.1048G>C p.V350L | Missense Mutation (SNP) | VAF 14/202 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.724); called by muse, mutect2
- SOX10 | c.1366G>A p.E456K | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- SREBF1 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 22/446 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- STAM2 | c.758C>G p.S253C | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- STC1 | c.317A>T p.K106M | Missense Mutation (SNP) | VAF 24/326 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); called by muse, mutect2
- SULT2A1 | c.463C>G p.Q155E | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.007); called by muse, mutect2
- SYT14 | c.1553G>T p.G518V | Missense Mutation (SNP) | VAF 26/418 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TBCCD1 | c.1368A>T p.R456S | Missense Mutation (SNP) | VAF 22/363 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- TBRG4 | c.613G>T p.A205S | Missense Mutation (SNP) | VAF 25/274 reads (9%) | SIFT tolerated (0.67); PolyPhen benign (0.001); called by muse, mutect2
- TEKT4 | c.458C>A p.P153H | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2
- TENM2 | c.300G>T p.M100I | Missense Mutation (SNP) | VAF 32/330 reads (10%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); called by muse, mutect2
- THSD1 | c.1777G>T p.E593* | Nonsense Mutation (SNP) | VAF 19/246 reads (8%) | called by muse, mutect2
- TMEM160 | c.76C>G p.Q26E | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2
- TMEM202 | c.147G>T p.M49I | Missense Mutation (SNP) | VAF 15/160 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2
- TRIM22 | c.1402A>T p.K468* | Nonsense Mutation (SNP) | VAF 20/179 reads (11%) | called by muse, mutect2, varscan2
- TSC22D1 | c.2444C>G p.S815* | Nonsense Mutation (SNP) | VAF 12/142 reads (8%) | called by muse, mutect2
- UNC13A | c.4812C>A p.F1604L | Missense Mutation (SNP) | VAF 22/234 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.392); called by muse, mutect2
- UNC13A | c.2007C>A p.D669E | Missense Mutation (SNP) | VAF 18/224 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.13); called by muse, mutect2
- XIRP2 | c.4519G>T p.D1507Y (on ENST00000628543; = p.D1682Y on NM_152381.6) | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ZNF580 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2
- ZNF677 | c.1469C>A p.T490N | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- ZNF732 | c.226G>T p.A76S | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.905); called by muse, mutect2
- ZSCAN25 | c.1257G>T p.E419D | Missense Mutation (SNP) | VAF 14/246 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.174); called by muse, mutect2
- ACOT12 | c.150C>G p.S50= | Silent (SNP) | VAF 16/180 reads (9%) | called by muse, mutect2
- ANK2 | c.1422C>A p.A474= | Silent (SNP) | VAF 26/377 reads (7%) | called by muse, mutect2
- ARHGAP6 | c.1230C>A p.V410= | Silent (SNP) | VAF 14/106 reads (13%) | called by muse, mutect2, varscan2
- ASXL3 | c.6624A>G p.E2208= | Silent (SNP) | VAF 11/134 reads (8%) | called by muse, mutect2
- ATXN10 | c.96C>T p.L32= | Silent (SNP) | VAF 18/300 reads (6%) | catalogued as rs1185569919; called by muse, mutect2
- BCDIN3D | c.552C>T p.A184= | Silent (SNP) | VAF 9/40 reads (23%) | called by muse, mutect2, varscan2
- CDYL2 | c.672G>T p.L224= | Silent (SNP) | VAF 9/99 reads (9%) | called by muse, mutect2
- CPZ | c.1452G>T p.L484= (on ENST00000360986 / NM_001014447.3; = p.L473= on NM_003652.3) | Silent (SNP) | VAF 19/212 reads (9%) | called by muse, mutect2
- CSNK2A3 | c.1035C>A p.P345= | Silent (SNP) | VAF 56/512 reads (11%) | catalogued as COSV57156602, COSV99923710; called by muse, mutect2, varscan2
- CSRNP1 | c.1482A>G p.S494= | Silent (SNP) | VAF 14/204 reads (7%) | called by muse, mutect2
- EPHB6 | c.2055G>T p.V685= | Silent (SNP) | VAF 30/484 reads (6%) | called by muse, mutect2
- FAM120C | c.600C>T p.H200= | Silent (SNP) | VAF 20/383 reads (5%) | catalogued as COSV100070209; called by muse, mutect2
- FAM47C | c.1221C>A p.P407= | Silent (SNP) | VAF 24/374 reads (6%) | called by muse, mutect2
- FGFR2 | c.882G>T p.V294= | Silent (SNP) | VAF 18/158 reads (11%) | called by muse, mutect2
- FLNA | c.78C>A p.A26= | Silent (SNP) | VAF 12/238 reads (5%) | called by muse, mutect2
- FLNC | c.3549A>T p.A1183= | Silent (SNP) | VAF 35/127 reads (28%) | called by muse, mutect2, varscan2
- GATM | c.366G>A p.K122= | Silent (SNP) | VAF 10/174 reads (6%) | catalogued as rs1456477402; ClinVar: likely benign; called by muse, mutect2
- HGF | c.1077G>T p.G359= | Silent (SNP) | VAF 18/330 reads (5%) | catalogued as COSV55956406; called by muse, mutect2
- KIF12 | c.651C>G p.L217= (on ENST00000640217; = p.L79= on NM_138424.1) | Silent (SNP) | VAF 20/390 reads (5%) | called by muse, mutect2
- KSR1 | c.1791C>T p.I597= (on ENST00000644974 / NM_001367810.1; = p.I482= on NM_014238.2) | Silent (SNP) | VAF 23/342 reads (7%) | catalogued as rs778099345, COSV99258184; called by muse, mutect2
- LIM2 | c.192C>A p.T64= (on ENST00000596399 / NM_001161748.2; = p.T106= on NM_030657.4) | Silent (SNP) | VAF 30/364 reads (8%) | called by muse, mutect2
- LRRC8B | c.1173C>T p.V391= | Silent (SNP) | VAF 5/84 reads (6%) | called by muse, mutect2
- MOB1A | c.123G>A p.L41= | Silent (SNP) | VAF 8/140 reads (6%) | called by muse, mutect2
- NOVA2 | c.930C>A p.A310= | Silent (SNP) | VAF 16/268 reads (6%) | catalogued as rs1386514633, COSV99611107; called by muse, mutect2
- OR2B11 | c.696C>A p.I232= | Silent (SNP) | VAF 6/84 reads (7%) | catalogued as COSV59511719; called by muse, mutect2
- OTOGL | c.2844C>T p.C948= (on ENST00000547103; = p.C939= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 41/299 reads (14%) | catalogued as rs371906002; called by muse, mutect2, varscan2
- PDE6B | c.241C>A p.R81= | Silent (SNP) | VAF 21/218 reads (10%) | called by muse, mutect2, varscan2
- RBM4 | c.30C>T p.P10= | Silent (SNP) | VAF 24/104 reads (23%) | catalogued as rs751493114; called by muse, varscan2
- RINT1 | c.1518G>A p.L506= | Silent (SNP) | VAF 6/96 reads (6%) | called by muse, mutect2
- RPL10L | c.414C>A p.I138= | Silent (SNP) | VAF 37/351 reads (11%) | catalogued as COSV53560548; called by muse, mutect2, varscan2
- RRAGA | c.75G>C p.S25= | Silent (SNP) | VAF 28/192 reads (15%) | called by muse, mutect2, varscan2
- RUNDC3A | c.525C>A p.I175= | Silent (SNP) | VAF 32/244 reads (13%) | catalogued as rs367958604; called by muse, mutect2, varscan2
- RUNDC3A | c.888G>A p.A296= | Silent (SNP) | VAF 17/184 reads (9%) | called by muse, mutect2
- SLC33A1 | c.372C>G p.L124= | Silent (SNP) | VAF 28/491 reads (6%) | catalogued as rs1302181647; called by muse, mutect2
- SLC6A16 | c.1068C>T p.S356= | Silent (SNP) | VAF 25/382 reads (7%) | catalogued as rs1262320003; called by muse, mutect2
- SLC6A5 | c.132C>T p.A44= | Silent (SNP) | VAF 21/213 reads (10%) | catalogued as rs780386706; called by muse, mutect2, varscan2
- SLC6A8 | c.1644C>T p.N548= | Silent (SNP) | VAF 28/324 reads (9%) | catalogued as rs373130978; called by muse, mutect2
- SPTB | c.3234C>A p.S1078= | Silent (SNP) | VAF 27/445 reads (6%) | called by muse, mutect2
- TAFA5 | c.84C>T p.I28= | Silent (SNP) | VAF 9/226 reads (4%) | catalogued as rs1168137470, COSV100385589; called by muse, mutect2
- TAL1 | c.84C>A p.P28= | Silent (SNP) | VAF 22/250 reads (9%) | catalogued as rs769376285; called by muse, mutect2
- TBX4 | c.714G>A p.L238= | Silent (SNP) | VAF 22/602 reads (4%) | called by muse, mutect2
- TCF7L2 | c.1071C>T p.F357= (on ENST00000355995 / NM_001367943.1; = p.F334= on NM_030756.5) | Silent (SNP) | VAF 9/150 reads (6%) | catalogued as COSV53337214; called by muse, mutect2
- TLN2 | c.2904G>T p.L968= | Silent (SNP) | VAF 8/102 reads (8%) | called by muse, mutect2
- TMEM51 | c.180C>T p.S60= | Silent (SNP) | VAF 44/425 reads (10%) | called by muse, mutect2, varscan2
- TMTC3 | c.2370T>C p.A790= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as COSV99898640; called by muse, mutect2, varscan2
- TRIM5 | c.960G>T p.V320= | Silent (SNP) | VAF 8/88 reads (9%) | called by muse, mutect2
- TSHZ3 | c.2418G>C p.V806= | Silent (SNP) | VAF 10/140 reads (7%) | catalogued as COSV53679552, COSV53682166; called by muse, mutect2
- UTP18 | c.324G>T p.R108= | Silent (SNP) | VAF 35/272 reads (13%) | called by muse, mutect2, varscan2
- XYLT2 | c.1296C>G p.L432= | Silent (SNP) | VAF 11/266 reads (4%) | called by muse, mutect2
- ZNF185 | c.153C>T p.R51= | Silent (SNP) | VAF 6/81 reads (7%) | called by muse, mutect2
- ACADSB | c.-7G>A | 5'UTR (SNP) | VAF 24/406 reads (6%) | called by muse, mutect2
- AFAP1 | c.1531-2655C>T | Intron (SNP) | VAF 26/580 reads (4%) | catalogued as COSV100631021; called by muse, mutect2
- BIRC3 | c.954-1208G>C | Intron (SNP) | VAF 6/97 reads (6%) | called by muse, mutect2
- C3orf84 | c.141+165G>A | Intron (SNP) | VAF 6/68 reads (9%) | catalogued as rs1450934340; called by muse, mutect2
- CDIPT | c.-107C>T | 5'UTR (SNP) | VAF 16/167 reads (10%) | called by muse, mutect2
- CEROX1 | n.3480G>A | RNA (SNP) | VAF 34/405 reads (8%) | catalogued as rs1328801567; called by muse, mutect2
- CFP | c.1244+49G>T | Intron (SNP) | VAF 20/168 reads (12%) | called by muse, mutect2, varscan2
- CHN2 | c.577-126G>C | Intron (SNP) | VAF 14/222 reads (6%) | called by muse, mutect2
- FAM90A20P | n.299A>C | RNA (SNP) | VAF 16/430 reads (4%) | called by muse, mutect2
- GTF2B | c.*18C>G | 3'UTR (SNP) | VAF 18/209 reads (9%) | called by muse, mutect2
- GTF2IRD2P1 | chr7:73269255 G>T | 5'Flank (SNP) | VAF 10/602 reads (2%) | called by muse, mutect2
- HBE1 | c.-267+159G>C | Intron (SNP) | VAF 16/167 reads (10%) | catalogued as COSV61163996; called by muse, mutect2
- HSP90AA4P | n.1950C>T | RNA (SNP) | VAF 12/252 reads (5%) | called by muse, mutect2
- KCND2 | c.-31G>A | 5'UTR (SNP) | VAF 14/291 reads (5%) | catalogued as rs928796482, COSV100473025; called by muse, mutect2
- KCNT1 | c.111-30G>T | Intron (SNP) | VAF 3/28 reads (11%) | catalogued as rs866953029; called by muse, mutect2
- LINC00243 | n.377G>C | RNA (SNP) | VAF 10/262 reads (4%) | called by muse, mutect2
- NEFM | chr8:24913747 G>A | 5'Flank (SNP) | VAF 6/92 reads (7%) | catalogued as rs1005412293; called by muse, mutect2
- NLGN4X | c.*33C>A | 3'UTR (SNP) | VAF 12/125 reads (10%) | called by muse, mutect2, varscan2
- PEG10 | c.*587C>G | 3'UTR (SNP) | VAF 19/215 reads (9%) | called by muse, mutect2
- PNLIPRP2 | chr10:116645102 G>T | 3'Flank (SNP) | VAF 8/149 reads (5%) | called by muse, mutect2
- PRKN | c.1083+3421G>T | Intron (SNP) | VAF 9/139 reads (6%) | catalogued as COSV58214063; called by muse, mutect2
- PRPF38A | c.291-129C>T | Intron (SNP) | VAF 10/136 reads (7%) | called by muse, mutect2
- PSEN2 | c.788-12C>T | Intron (SNP) | VAF 16/488 reads (3%) | called by muse, mutect2
- R3HDML | chr20:44355763 G>T | 3'Flank (SNP) | VAF 24/409 reads (6%) | called by muse, mutect2
- RASSF1 | c.369+382G>A | Intron (SNP) | VAF 5/67 reads (7%) | called by muse, mutect2
- SCN1A | c.-4C>A | 5'UTR (SNP) | VAF 11/120 reads (9%) | called by muse, mutect2
- SHISA9 | c.-36G>T | 5'UTR (SNP) | VAF 10/164 reads (6%) | called by muse, mutect2
- SLC47A1P2 | n.193T>C | RNA (SNP) | VAF 12/190 reads (6%) | called by muse, mutect2
- SYT7 | c.215+4205C>T | Intron (SNP) | VAF 14/172 reads (8%) | called by muse, mutect2
- TMEM135 | c.*4379T>A | 3'UTR (SNP) | VAF 6/103 reads (6%) | catalogued as rs1157642293; called by muse, mutect2
- TPO | c.482+2496C>A | Intron (SNP) | VAF 14/149 reads (9%) | catalogued as COSV61095807; called by muse, mutect2, varscan2
- TRIM15 | c.*208C>A | 3'UTR (SNP) | VAF 8/104 reads (8%) | called by muse, mutect2
- UAP1L1 | chr9:137086543 C>G | 3'Flank (SNP) | VAF 8/110 reads (7%) | called by muse, mutect2
- WWOX | c.*179G>T | 3'UTR (SNP) | VAF 25/323 reads (8%) | called by muse, mutect2
- ZNRD2 | chr11:65572461 C>T | 3'Flank (SNP) | VAF 40/398 reads (10%) | called by muse, mutect2, varscan2
